Gene-level copy-number profile of tumor specimen ALCH-B4SE-TTP1-A from ALCHEMIST case ALCH-B4SE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 82.8 years (30,249 days).
Specimen ALCH-B4SE-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bbbe09f2-4fb0-4d49-81c5-bf4f500d9196.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4SE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,250 have no estimate.
https://portal.gdc.cancer.gov/files/e55b1598-d8b4-468a-8087-0e7f141ea846

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 118; copy number 1: 6,462; copy number 2: 44,367; copy number 3: 6,426; copy number 4: 328; copy number 5: 92; copy number 6: 172; copy number 7: 7; copy number 8: 30; copy number 9: 92; copy number 10: 30; copy number 11: 16; copy number 12: 79; copy number 13: 80; copy number 14: 4; copy number 16: 4; copy number 22: 4; copy number 23: 4; copy number 24: 14; copy number 27: 14; copy number 44: 1; copy number 46: 1; copy number 58: 4; copy number 59: 2; copy number 67: 2; copy number 69: 9; copy number 73: 2; copy number 87: 9.

Homozygous deletions (total copy number 0; autosomes only): 118 genes in 30 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–522,928, 31 genes: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr1:2,425,980–2,505,532, 3 genes: PLCH2, AL139246.1, AL139246.4.
- chr1:243,005,845–243,101,744, 6 genes: AL606534.3, SEPTIN14P21, CICP21, AL606534.4, LINC01347, RNU6-747P.
- chr2:61,710,076–61,710,978, 1 gene: AC108039.1.
- chr2:106,487,364–106,544,297, 1 gene (within-gene range 0–2): CD8B2.
- chr4:49,203,171–49,589,529, 19 genes: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr4:118,460,224–118,460,301, 1 gene: AC092670.1.
- chr5:100,062,275–100,067,954, 1 gene: GUSBP7.
- chr7:56,875,385–56,882,146, 1 gene: AC118758.1.
- chr8:12,128,107–12,139,077, 3 genes (within-gene range 0–2): AC130366.1, USP17L7, USP17L2.
- chr8:12,628,476–12,629,256, 1 gene: RPS3AP35.
- chr9:64,621,560–64,637,586, 1 gene: AQP7P2.
- chr9:136,519,568–136,519,626, 1 gene (within-gene range 0–1): MIR4673.
- chr10:14,061–74,163, 3 genes: AC215217.1, AL713922.1, TUBB8.
- chr10:77,776,951–77,793,176, 3 genes (within-gene range 0–1): RNU6-1266P, IMPDH1P5, AL450306.1.
- chr10:125,166,677–125,166,937, 1 gene: MRPS21P6.
- chr12:37,575,587–37,576,384, 1 gene: ZNF970P.
- chr12:132,593,031–132,687,376, 5 genes: AC131212.1, LRCOL1, P2RX2, AC131212.4, POLE.
- chr13:113,276,616–113,277,734, 1 gene: LDHBP1.
- chr14:93,138,066–93,138,465, 1 gene: CYB5AP3.
- chr14:102,539,644–102,539,726, 1 gene: MIR4309.
- chr15:28,857,882–28,858,398, 1 gene (within-gene range 0–2): AC174071.1.
- chr17:81,650,459–81,663,112, 1 gene: PDE6G.
- chr18:21,928,985–21,929,094, 1 gene: RNA5SP451.
- chr19:38,361,795–38,362,484, 1 gene (within-gene range 0–2): AC005625.1.
- chr19:39,196,964–39,204,263, 2 genes: NCCRP1, SYCN.
- chr19:53,748,636–53,789,168, 21 genes: MIR521-1, RNU6-751P, MIR522, MIR519A1, MIR527, MIR516A1, MIR1283-2, RNU6-1041P, MIR516A2, AC011453.1, MIR519A2, RNU6-165P, HMGN1P32, SEPTIN7P8, AC008753.1, AC008753.3, MIR371A, MIR371B, MIR372, MIR373, AC008753.2.
- chr20:38,711,821–38,712,103, 1 gene: Metazoa_SRP.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.
- chr21:44,158,740–44,194,338, 3 genes: LINC01678, AP001056.2, AP001056.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 669 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,838,110–42,703,805, 82 genes, copy number 12–24 (broad region; genes not listed).
- chr1:44,850,522–46,036,122, 36 genes, copy number 12: EIF2B3, RNA5SP47, CCNB1IP1P1, PPIAP35, MRPS17P1, HECTD3, UROD, ZSWIM5, OSTCP5, LINC01144, HPDL, MUTYH, AL451136.1, TOE1, TESK2, PPIAP36, CCDC163, MMACHC, PRDX1, HMGB1P48, AKR1A1, AL355480.3, AL355480.1, NASP, AL355480.2, AL355480.4, CCDC17, GPBP1L1, RPS15AP10, AL604028.2, TMEM69, IPP, AL604028.1, AL603882.1, MAST2, TMA16P2.
- chr1:46,246,461–46,365,152, 4 genes, copy number 13: RAD54L, LRRC41, UQCRH, NSUN4.
- chr1:196,977,556–197,067,260, 2 genes, copy number 67: CFHR5, F13B.
- chr1:197,153,682–197,223,255, 2 genes, copy number 13–16: ZBTB41, AL513325.1.
- chr1:197,504,748–197,935,478, 8 genes, copy number 11–73 (within-gene range 11–102): DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1, C1orf53, LHX9.
- chr1:198,523,222–198,540,945, 1 gene, copy number 11: ATP6V1G3.
- chr1:198,777,861–198,949,805, 4 genes, copy number 7–14: MIR181A1HG, MIR181B1, MIR181A1, AC096631.2.
- chr1:199,888,159–199,909,648, 2 genes, copy number 11: RNU6-778P, AL445687.2.
- chr1:202,331,657–202,592,706, 2 genes, copy number 11–46 (within-gene range 3–46): UBE2T, PPP1R12B.
- chr1:202,438,396–202,710,454, 6 genes, copy number 11: AC099336.1, AC099336.2, SNORA70, SYT2, AC104463.2, AC104463.1.
- chr1:203,273,221–203,508,949, 9 genes, copy number 69 (within-gene range 2–69): LINC01353, LINC01136, BTG2, RNU6-487P, FMOD, AL359837.1, LARP7P1, PRELP, OPTC.
- chr1:203,765,177–204,041,265, 11 genes, copy number 59–87: LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, LINC00303.
- chr1:204,516,379–204,616,565, 4 genes, copy number 58: MDM4, AL512306.1, RNA5SP74, AL512306.3.
- chr1:205,504,596–206,734,281, 41 genes, copy number 13–27: CDK18, RNU2-19P, MFSD4A, RNU6-418P, ELK4, AC096533.1, SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1, RAB7B, CTSE, BX571818.1, RHEX, AC244035.3, AVPR1B, AC244035.1, AC244035.4, RPL22P4, AC244035.2, FAM72A, SRGAP2, AC244023.1, IKBKE, MIR6769B, C1orf147, AC244034.2, RASSF5, AC244034.1, AC244034.3, EIF2D, DYRK3-AS1, DYRK3, MAPKAPK2, AL591846.1.
- chr2:24,199,839–24,201,698, 1 gene, copy number 5 (within-gene range 2–5): AC008073.1.
- chr3:187,721,377–187,746,028, 2 genes, copy number 6 (within-gene range 2–6): BCL6, AC072022.2.
- chr5:88,692,651–88,692,859, 1 gene, copy number 7 (within-gene range 2–7): AC008525.2.
- chr7:104,940,943–105,013,044, 2 genes, copy number 5 (within-gene range 2–5): AC007384.1, LINC01004.
- chr8:124,306,189–124,372,692, 1 gene, copy number 5: TMEM65.
- chr10:87,341,685–87,357,882, 1 gene, copy number 5 (within-gene range 1–5): LINC00863.
- chr13:99,981,784–99,997,909, 2 genes, copy number 7: ZIC2, LINC00554.
- chr14:29,210,986–35,404,749, 106 genes, copy number 6 (broad region; genes not listed).
- chr14:35,511,825–37,172,606, 36 genes, copy number 7–13 (within-gene range 2–13): KRT18P6, INSM2, RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2, AL133304.3, AL133304.1, ILF2P2, AL133304.2, LINC00609, PTCSC3, AL162511.1, RN7SKP21, MBIP, AL132857.1, DPPA3P2, RNU7-93P, SFTA3, SFTA3, NKX2-1, NKX2-1-AS1, PHKBP2, RPL29P3, NKX2-8, RN7SKP257, AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503.
- chr14:106,636,672–106,636,786, 1 gene, copy number 10 (within-gene range 2–10): RNA5SP389.
- chr14:106,643,142–106,652,681, 3 genes, copy number 10 (within-gene range 2–10): IGHV3-62, IGHVII-62-1, IGHV3-63.
- chr14:106,675,017–106,879,812, 26 genes, copy number 10 (within-gene range 2–10): IGHV3-66, IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68, IGHV1-69, IGHV2-70D, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr15:101,875,964–101,876,901, 1 gene, copy number 6: OR4F28P.
- chr15:101,922,042–101,979,093, 9 genes, copy number 5–6: OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr16:3,156,736–3,157,483, 1 gene, copy number 9: AC108134.2.
- chr17:7,315,628–7,329,393, 1 gene, copy number 5 (within-gene range 3–5): NEURL4.
- chr20:35,302,566–35,742,312, 21 genes, copy number 5: UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39.
- chr20:55,074,644–58,451,101, 60 genes, copy number 5: RPL12P4, LINC01440, LINC01441, AL160413.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P, AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1, RBM38, HMGB1P1, CTCFL, PCK1, AL035541.1, ZBP1, PMEPA1, NKILA, AL162291.1, AL354984.1, LINC01742, AL354984.2, AL354984.3, C20orf85, ANKRD60, PPP4R1L, RAB22A, VAPB.
- chr20:58,842,433–64,327,972, 177 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr21:43,446,601–43,479,534, 2 genes, copy number 14–44 (within-gene range 4–44): LINC00319, LINC00313.
- chr21:44,133,610–44,210,114, 1 gene, copy number 7 (within-gene range 0–7): GATD3A.

Autosomal genes at a single copy (total copy number 1): 6,462. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
